Somatic mutation profile of tumor specimen MP2PRT-PAVFRE-TMP1-A (aliquot MP2PRT-PAVFRE-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVFRE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (591 days).
Specimen MP2PRT-PAVFRE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbc00966-c9da-452a-933d-db7724d76d4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFRE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFRE-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61d6d58b-7c70-47b9-8da1-f191ddf46bed

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1504T>G p.S502A | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs121918458, CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs148254279, COSV51026711; called by muse, mutect2, varscan2
- ANKFN1 | c.3448C>T p.R1150W (on ENST00000653862; = p.R1003W on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/649 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1256527835, COSV73719534; called by muse, mutect2, varscan2
- C7 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as rs976896424, CD100234, COSV100496793; called by muse, mutect2, varscan2
- EPPK1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 287/1001 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781906539, COSV101599965; called by muse, mutect2, varscan2
- GALNT17 | c.422+1del p.X141_splice | Splice Site (DEL) | VAF 95/272 reads (35%) | catalogued as COSV61164109; called by mutect2, pindel, varscan2
- KMT2D | c.7095C>G p.H2365Q | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- LRIG3 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.211); called by muse, mutect2
- CD163L1 | c.3390C>T p.D1130= | Silent (SNP) | VAF 113/312 reads (36%) | catalogued as rs769675914, COSV58018746; called by muse, varscan2
- MYO1H | c.135C>T p.V45= | Silent (SNP) | VAF 102/415 reads (25%) | catalogued as rs748204818, COSV60446677; called by muse, mutect2
- SCART1 | c.2883C>T p.Y961= | Silent (SNP) | VAF 115/486 reads (24%) | catalogued as rs751485645; called by muse, varscan2
